Gene-level copy-number profile of tumor specimen TCGA-2Z-A9JL-01A from TCGA case TCGA-2Z-A9JL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 47.5 years (17,367 days).
Specimen TCGA-2Z-A9JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.a3bd574c-824e-48a4-9ecd-f55d250e8c6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Z-A9JL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de4c3601-9053-474b-bf91-5ee8f1132533

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 52,781; copy number 3: 4,063; copy number 4: 451; copy number 5: 46; copy number 6: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Z-A9JL-01A-11D-A42I-01): tumor purity 0.78, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 103 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:115,581,315–117,323,152, 46 genes, copy number 6: SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr7:117,332,761–117,428,123, 2 genes, copy number 6: AC002465.1, ASZ1.
- chr7:120,005,976–123,971,414, 55 genes, copy number 5–6: RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
